Gene-level copy-number profile of tumor specimen TCGA-WT-AB44-01A from TCGA case TCGA-WT-AB44, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA.
Specimen TCGA-WT-AB44-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5b7aacc0-7bc9-4318-b439-e5b15e61cdfc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WT-AB44-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e8de7ea-9310-496d-95ae-b54c2f5c2bd8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,729; copy number 1: 8,967; copy number 2: 40,052; copy number 3: 6,774; copy number 4: 82; copy number 5: 1,279; copy number 6: 1,316; copy number 7: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WT-AB44-01A-11D-A41E-01): tumor purity 0.61, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,492,017–89,504,460, 1 gene: AC092123.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,659 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–248,919,946, 2,595 genes, copy number 5–6 (broad region; genes not listed).
- chr14:105,736,343–106,117,204, 64 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
